Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7415, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7415-01A (Primary Tumor).

[page 1 of 2]
DIAGNOSIS

(A) LEFT PYRIFORM SINUS:

INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CARCINOMA.

(B) PHARYNGEAL PLEXUS OF VAGUS NERVE:

Segment of nerve, no tumor present.

(C) TOTAL LARYNGOPHARYNGECTOMY, BILATERAL NECK DISSECTIONS, EXCISION OF LEFT NECK SKIN, LEFT THYROIDECTOMY:

INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CARCINOMA OF THE LEFT PYRIFORM SINUS EXTENDING INTO THE LEFT ARYEPIGLOTTIC FOLD, ESOPHAGUS, LEFT PARAGLOTTIC SPACE, LEFT PARATRACHEAL/PARA-ESOPHAGEAL SOFT TISSUE AND LEFT THYROID.

VASCULAR/LYMPHATIC INVASION PRESENT.

Surgical margins, free of tumor.

METASTATIC SQUAMOUS CARCINOMA IN 11 OF 53 LEFT CERVICAL LYMPH NODES (11/53), 1/2 SUBMANDIBULAR/SUBMAXILLARY, LEVEL 2; 5/7 SUBDIGASTRIC, LEVEL 3; 3/8 MIDJUGULAR, LEVEL 4; 1/7 LOWER JUGULAR, LEVEL 5; 0/8 UPPER POSTERIOR CERVICAL, LEVEL 6; 0/7 MID POSTERIOR CERVICAL, LEVEL 7; 0/5 LOWER POSTERIOR CERVICAL, LEVEL 8; 1/9 SUPRACLAVICULAR/SCALENE, LEVEL 9 LYMPH NODES. (SEE COMMENT)

METASTATIC SQUAMOUS CARCINOMA IN 5 OF 29 RIGHT CERVICAL LYMPH NODES (5/29) (0/5 SUBMANDIBULAR/SUBMAXILLARY, LEVEL 2; 2/4 SUBDIGASTRIC, LEVEL 3; 1/1 MIDJUGULAR, LEVEL 4; 0/4 LOWER JUGULAR, LEVEL 5; 1/2 UPPER POSTERIOR CERVICAL, LEVEL 6; 1/5 MID POSTERIOR CERVICAL, LEVEL 7; 0/8 LOWER POSTERIOR CERVICAL, LEVEL 8 LYMPH NODES. (SEE COMMENT)

METASTATIC SQUAMOUS CARCINOMA IN 1 OF 2 PERITHYROIDAL LYMPH NODES, LEVEL 10 (1/2).

Right and left submandibular glands, no tumor present.

Segment of left jugular vein, no tumor present.

Segment of left vagus, no tumor present.

One parathyroid gland, no tumor present.

Skin with marked solar elastosis and subcutaneous tissue of the anterior neck with marked acute inflammation.

(D) NEW ESOPHAGEAL MARGIN:

Portion of esophagus, no tumor present.

COMMENT

The tumor in the left pyriform sinus is 9.5 cm in greatest dimension. The largest lymph node involved by metastatic tumor is 2.5 cm in largest dimension and located in the left subdigastric area. Approximately 50% of it is replaced by metastatic tumor. However, many of the other lymph nodes involved by metastatic tumor are almost completely replaced by the metastasis, there is extranodal extension measuring at least 3.0 mm.

SPECIMEN

(A) LEFT PYRIFORM SINUS:

[page 2 of 2]
-
- (B) PHARYNGEAL PLEXUS OF VAGUS NERVE:
- (C) TOTAL LARYNGOPHARYNGECTOMY, BILATERAL NECK DISSECTIONS, EXCISION OF LEFT
- (D) NEW ESOPHAGEAL MARGIN:

SNOMED CODES

T-55300,M-80703,T-C4200,M-80703

Source: NCI Genomic Data Commons file 7eb3fab0-26c1-4cbf-941f-270b853eba23 (TCGA-CV-7415.DAB06915-E50B-42F4-A6C8-DE0DBDD4B6F7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).